Gene-level copy-number profile of tumor specimen C3L-02165-01 from CPTAC case C3L-02165, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.8 years (23,666 days).
Specimen C3L-02165-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 34d57868-9613-476b-b15a-09072218b270.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02165-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/5fc1b9a3-1e06-4254-8d8c-ab9d0ad7cba5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 596; copy number 1: 9,995; copy number 2: 40,725; copy number 3: 6,756; copy number 4: 838; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:984,332–2,164,468, 78 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,505,943–28,539,300, 1 gene, copy number 5 (within-gene range 2–5): RCC1.
- chr1:28,526,318–28,527,227, 1 gene, copy number 5: PRDX3P2.
- chr9:128,275,379–128,316,123, 1 gene, copy number 5 (within-gene range 2–5): SWI5.

Autosomal genes at a single copy (total copy number 1): 7,661. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
